Somatic mutation profile of tumor specimen TCGA-H2-A26U-01A (aliquot TCGA-H2-A26U-01A-11D-A16O-08) from TCGA case TCGA-H2-A26U, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 54.6 years (19,927 days).
Specimen TCGA-H2-A26U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abb6172a-f471-44e2-9b97-ba58a96f6db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H2-A26U-10A (Blood Derived Normal), aliquot TCGA-H2-A26U-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b88fc47-a9cf-4bd9-838c-18cd2b17864f

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- CEP68 | c.1944_1947del p.D649Tfs*26 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs1443698418; called by mutect2, pindel, varscan2
- HIF3A | c.1148C>T p.T383I (on ENST00000377670 / NM_152795.4; = p.T314I on NM_022462.4) | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV52199949; called by muse, varscan2
- LAMA4 | c.2348A>T p.D783V (on ENST00000230538 / NM_001105206.3; = p.D776V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV57898936; called by muse, mutect2, varscan2
- MS4A2 | c.704del p.P235Qfs*19 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- CUX1 | c.2955G>A p.P985= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as rs373412162; called by muse, mutect2
